TCGA case TCGA-23-1116 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/70fe08bd-a0b4-4a88-b82e-813b176f8e40

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 83 years; Vital status: Dead; Days to death: 592 days (1.6 years); Population group: Ashkenazi Jew.

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 83.4 years (30,464 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 592 days (1.6 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: >20 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 187 days; Number of cycles: 6; Treatment dose: 2,100 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 187 days; Number of cycles: 6; Treatment dose: 1,746 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 306 days; Days to treatment end: 418 days (1.1 years); Number of cycles: 6; Treatment dose: 1,530 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 306 days; Days to treatment end: 418 days (1.1 years); Number of cycles: 6; Treatment dose: 11,028 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 84.2 years (30,750 days); Days to diagnosis: 286 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 84.2 years (30,750 days); Days to diagnosis: 286 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 286 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 286 days.
- Days to follow up: 592 days (1.6 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 139.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-23-1116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-23-1116-01A-01-BS1: Section location: Bottom; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5.
  Slide TCGA-23-1116-01A-01-TS1: Section location: Top; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0.
- Sample TCGA-23-1116-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-23-1116-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Jewish religion heritage indicator: Ashkenazi; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IP; Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Gemzar.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy of breast cancer.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-23-1116-01A-01D-0428-01): tumor purity 0.34, ploidy 3.37, whole-genome doublings 1.
